Surgical pathology report (de-identified scan), TCGA case TCGA-IF-A4AJ, project TCGA-SARC (Sarcoma), tissue source site University of Texas MD Anderson Cancer Center, specimen TCGA-IF-A4AJ-01A (Primary Tumor).

Specimen Date/Time:

** Case imported from

** For cases prior to

The format of this report does not match the original case. **

DIAGNOSIS

(A) LEFT BELOW THE KNEE AMPUTATION:

HIGH GRADE LEIOMYOSARCOMA, FOCALLY INVADING FIBULA, WITH EVIDENCE OF
OF VASCULAR INVASION. (SEE COMMENT)

Surgical margins of resection free of tumor

COMMENT: The tumor is present within the deep soft tissues of the lower leg
and measures 10.0 cm in maximum dimension. The tumor invades superficially
into the fibula, with destruction of the cortical bone at the site of a
fracture in the middle of the diaphysis. The tumor is present within a
medium sized vessel which on microscopic examination appears to be a vein.
Tumor necrosis is less than 15%.

SPECIMEN

(A) LEFT BELOW THE KNEE AMPUTATION:

SNOMED CODES

T-D9400,M-88903

-----END OF REPORT-----

ICD-0.3

Leiomyosarcoma, NOS 8890/3

Site: Fibula C40.2

lw
9/24/12

ICD/A Discrepancy		☒

Source: NCI Genomic Data Commons file 4949614a-b465-4f4e-9103-4a646b64812d (TCGA-IF-A4AJ.D2E2057A-E810-4EDD-8FBF-731C84F9418F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).